Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8592, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8592-01A (Primary Tumor).

[page 1 of 4]
[REDACTED]

[REDACTED] Case ID	Gross Description	Microscopic Description
[REDACTED]		

[page 2 of 4]
Diagnosis Details	Comments

[page 3 of 4]
Formatted Path Report

STOMACH TISSUE CHECKLIST

Specimen type: Gastrectomy
Tumor site: Fundus
Tumor size: 11 x 9 x 1 cm
Tumor features: Ulcerated
Histologic type: Adenocarcinoma, diffuse type
Histologic grade: Not specified
Tumor extent: Adjacent structures (specify) - Lesser omentum
Lymph nodes: 1/3 positive for metastasis (Intraabdominal 1/3)
Lymphatic invasion: Not specified
Venous invasion: Not specified
Perineural invasion: Not specified
Margins: Uninvolved
Evidence of neo-adjuvant treatment: Not specified
Additional pathologic findings: Not specified
Comments: None

ID

[page 4 of 4]
Excision date

Source: NCI Genomic Data Commons file c45dbb49-5692-4ddd-b750-522e9dae98b7 (TCGA-BR-8592.3199EFB2-5F90-451A-AE61-C1D5E9888859.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).